Somatic mutation profile of tumor specimen TCGA-FD-A43X-01A (aliquot TCGA-FD-A43X-01A-11D-A23U-08) from TCGA case TCGA-FD-A43X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 84.2 years (30,764 days).
Specimen TCGA-FD-A43X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432b3a32-2a82-4153-bbc5-1fadc82fc410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A43X-10A (Blood Derived Normal), aliquot TCGA-FD-A43X-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e16bcc04-e84b-4d3b-9aa8-dc82b6d815bc

The open-access MAF lists 370 somatic variants for this specimen: 265 protein-altering or splice-affecting, 94 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 94, Nonsense Mutation 33, Intron 6, Splice Site 6, Frame Shift Del 4, Frame Shift Ins 2, RNA 2, 5'UTR 2, Translation Start Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNM1L | c.346_347del p.E116Kfs*6 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs879255687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HCN1 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs587777494, CM145439, COSV57508227; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs730880870, CM066922, COSV62518906; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52638304; called by muse, mutect2, varscan2
- ABCC5 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV55589617; called by muse, mutect2, varscan2
- ACSL5 | c.685G>A p.E229K (on ENST00000354273; = p.E285K on NM_016234.3) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV61130451; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 100/178 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769764386, COSV54442748; called by muse, mutect2
- ADCY6 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100326666, COSV100326991; called by muse, mutect2
- ADD1 | c.819C>G p.Y273* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as COSV99297171; called by muse, mutect2, varscan2
- ADGRB1 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 91/166 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV60096109; called by muse, mutect2, varscan2
- AIFM3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1441375131, COSV58999216; called by muse, varscan2
- AKAP12 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as COSV53574490; called by muse, mutect2, varscan2
- ALPK2 | c.5125G>C p.E1709Q | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV64492775; called by muse, mutect2, varscan2
- ANK1 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55880597; called by muse, mutect2, varscan2
- ANKRD11 | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV56360352; called by muse, mutect2, varscan2
- API5 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66633143; called by muse, mutect2, varscan2
- ARID3A | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 63/197 reads (32%) | catalogued as COSV99708574; called by muse, mutect2, varscan2
- ARID3A | c.1763C>G p.S588* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs762759062, COSV99708575; called by muse, varscan2
- ARID4B | c.2928G>C p.E976D | Missense Mutation (SNP) | VAF 131/178 reads (74%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV51602722; called by muse, mutect2, varscan2
- ARNT | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 93/131 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV62230580; called by muse, mutect2, varscan2
- ARNT2 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 117/175 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57584909; called by muse, mutect2, varscan2
- ARSH | c.901+2T>G p.X301_splice | Splice Site (SNP) | VAF 26/26 reads (100%) | catalogued as COSV66962902; called by muse, mutect2, varscan2
- ATE1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV56435920; called by muse, mutect2, varscan2
- ATP5F1C | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as COSV100184430; called by muse, mutect2, varscan2
- BDNF | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 102/213 reads (48%) | catalogued as COSV100151992, COSV59234276; called by muse, mutect2, varscan2
- BICD1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55678772; called by muse, mutect2, varscan2
- BRIP1 | c.1899C>G p.I633M | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs28997572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BST1 | c.423G>C p.L141F | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53946612; called by muse, mutect2, varscan2
- CADPS2 | c.2361G>A p.M787I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57361778; called by muse, mutect2, varscan2
- CATSPERG | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV53048477; called by muse, mutect2, varscan2
- CCN5 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51936118, COSV51937228; called by muse, mutect2, varscan2
- CCNI | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV52959669; called by muse, mutect2, varscan2
- CD200 | c.470C>T p.S157L (on ENST00000473539 / NM_001004196.3; = p.S132L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1304267717, COSV100238202, COSV59863162; called by muse, mutect2, varscan2
- CDC45 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 105/200 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54245145; called by muse, mutect2, varscan2
- CDCA4 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs775051889, COSV60315334; called by muse, mutect2, varscan2
- CDCA7 | c.905G>A p.R302Q (on ENST00000347703 / NM_145810.3; = p.R381Q on NM_031942.5) | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs748528043, COSV60720069, COSV60720142; called by muse, mutect2, varscan2
- CDCP1 | c.1718C>A p.S573Y | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56105327; called by muse, mutect2, varscan2
- CDHR2 | c.3808C>T p.H1270Y | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1382862612, COSV56138391; called by muse, mutect2, varscan2
- CEP135 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99954957; called by muse, varscan2
- CEP135 | c.2965G>C p.D989H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57259781; called by muse, varscan2
- CFAP46 | c.7502-1G>C p.X2501_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99585726; called by muse, mutect2, varscan2
- CLK2 | c.1369G>A p.E457K (on ENST00000368361 / NM_001294339.2; = p.E456K on NM_003993.4) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV56944998; called by muse, mutect2, varscan2
- CMTM6 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV52750130; called by muse, mutect2, varscan2
- COL14A1 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52853646; called by muse, mutect2, varscan2
- COL6A3 | c.3628del p.R1210Afs*4 | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | catalogued as COSV55102911; called by mutect2, pindel, varscan2
- COMTD1 | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.226); catalogued as COSV100041158, COSV100041167; called by muse, mutect2, varscan2
- CPNE7 | c.891G>C p.E297D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV52012664; called by muse, mutect2, varscan2
- CREB3 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 97/102 reads (95%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1325845649, COSV59207099; called by muse, mutect2, varscan2
- CUL4A | c.2112G>A p.M704I (on ENST00000375440 / NM_001008895.4; = p.M604I on NM_003589.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58372099; called by muse, mutect2, varscan2
- CUTA | c.304C>G p.Q102E (on ENST00000488034 / NM_001014840.2; = p.Q79E on NM_015921.3) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV53380973; called by muse, mutect2, varscan2
- CUTA | c.161C>T p.S54L (on ENST00000488034 / NM_001014840.2; = p.S31L on NM_015921.3) | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV53380983; called by muse, mutect2, varscan2
- CYP2C8 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV64877011; called by muse, mutect2, varscan2
- DACH1 | c.2122C>A p.Q708K (on ENST00000619232 / NM_001366712.1; = p.Q454K on NM_004392.6) | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as rs957975990, COSV57498441; called by muse, mutect2, varscan2
- DALRD3 | c.1064-1G>C p.X355_splice (on ENST00000341949 / NM_001009996.3; = p.X188_splice on NM_018114.5) | Splice Site (SNP) | VAF 23/44 reads (52%) | catalogued as COSV58243908, COSV58244878; called by muse, mutect2, varscan2
- DCLK1 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55184983; called by muse, mutect2, varscan2
- DCTN1 | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV62620401; called by muse, mutect2, varscan2
- DDIAS | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV61271976; called by muse, mutect2, varscan2
- DLC1 | c.2152G>A p.A718T (on ENST00000276297 / NM_001348081.2; = p.A281T on NM_006094.5) | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV52288290; called by muse, mutect2, varscan2
- DNAJC16 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs143679565; called by muse, mutect2, varscan2
- DSCAML1 | c.4082C>A p.T1361K (on ENST00000321322; = p.T1301K on NM_020693.4) | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58389842; called by muse, mutect2, varscan2
- DSP | c.7823C>G p.S2608C | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65792552; called by muse, mutect2, varscan2
- DYSF | c.4510-2A>C p.X1504_splice | Splice Site (SNP) | VAF 91/205 reads (44%) | catalogued as COSV50313034; called by muse, mutect2, varscan2
- EGR1 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1387817209, COSV53518314; called by muse, mutect2, varscan2
- EGR4 | c.1551C>G p.I517M (on ENST00000545030; = p.I414M on NM_001965.4) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71532003; called by muse, mutect2, varscan2
- ELP5 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs563674612, COSV63039315; called by muse, mutect2, varscan2
- EMSY | c.3389C>T p.S1130L | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV58259893; called by muse, mutect2, varscan2
- EPS15L1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50168540; called by muse, mutect2, varscan2
- EPS15L1 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV50168553; called by muse, mutect2, varscan2
- EXOSC10 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs1176642616, COSV58665211; called by muse, mutect2, varscan2
- FAM47A | c.1630C>G p.R544G | Missense Mutation (SNP) | VAF 71/74 reads (96%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.858); catalogued as COSV60496368, COSV60499742; called by muse, mutect2, varscan2
- FBN2 | c.6880G>A p.D2294N | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52510691; called by muse, mutect2, varscan2
- FETUB | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.485); catalogued as COSV54005535, COSV99409137; called by muse, mutect2, varscan2
- FGD5 | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV53242079; called by muse, mutect2, varscan2
- FLNC | c.6087C>G p.F2029L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV57955393; called by muse, mutect2, varscan2
- FNDC7 | c.986A>T p.H329L | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.474); catalogued as COSV54753166; called by muse, mutect2, varscan2
- FOXA2 | c.917C>G p.S306W (on ENST00000377115 / NM_153675.3; = p.S312W on NM_021784.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV101008541; called by muse, mutect2, varscan2
- FSIP1 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as rs778215635, COSV100618393; called by muse, mutect2
- GABRA6 | c.1342G>C p.V448L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as rs755727293, COSV50880566; called by muse, mutect2, varscan2
- GDF10 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs985793502; called by muse, mutect2, varscan2
- GINS4 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV99394687; called by muse, mutect2, varscan2
- GLI4 | c.624G>C p.E208D | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs778175890, COSV60681936; called by muse, mutect2, varscan2
- GLYR1 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58926951; called by muse, mutect2, varscan2
- GPR162 | c.1505G>A p.R502Q (on ENST00000311268 / NM_019858.2; = p.R218Q on NM_014449.2) | Missense Mutation (SNP) | VAF 119/214 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); catalogued as rs781892948, COSV51832908, COSV51836729; called by muse, mutect2, varscan2
- GRAMD1B | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs1284979934, COSV59203715; called by muse, mutect2, varscan2
- GUCY1A2 | c.302C>G p.S101W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV56484019, COSV99977416; called by muse, mutect2, varscan2
- H6PD | c.1880C>G p.S627* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as rs769215400, COSV66231465; called by muse, mutect2, varscan2
- HAUS5 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs561793567, COSV52547736; called by muse, mutect2, varscan2
- HCN1 | c.2425G>T p.G809C | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as COSV57508216; called by muse, mutect2, varscan2
- HRH1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as COSV67955407, COSV67956142; called by muse, mutect2, varscan2
- HSP90AA1 | c.1122_1123del p.C374* | Nonsense Mutation (DEL) | VAF 32/83 reads (39%) | catalogued as rs1327375632; called by pindel, varscan2
- HTT | c.8548G>C p.E2850Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV61861574; called by muse, varscan2
- HTT | c.8663C>G p.S2888C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374836871; called by mutect2, varscan2
- HUNK | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs141493785; called by muse, mutect2, varscan2
- IFIT5 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as rs777935444, COSV65655548; called by muse, mutect2, varscan2
- IGDCC4 | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61536696, COSV61538238; called by muse, mutect2, varscan2
- INIP | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV65295443; called by muse, mutect2, varscan2
- INPPL1 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs927834612, COSV53355273; called by muse, mutect2, varscan2
- INTS3 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59676481; called by muse, mutect2, varscan2
- IP6K1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.179); catalogued as COSV58663546; called by muse, mutect2, varscan2
- ITGA1 | c.1170G>A p.W390* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99252330; called by muse, mutect2
- KANSL1L | c.1643T>C p.L548P | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347183219, COSV55991944; called by muse, mutect2, varscan2
- KARS1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV56692001; called by muse, mutect2, varscan2
- KAT5 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV57729532; called by muse, mutect2, varscan2
- KDM6A | c.3439C>T p.Q1147* | Nonsense Mutation (SNP) | VAF 30/31 reads (97%) | catalogued as COSV65037827, COSV65041240; called by muse, mutect2, varscan2
- KIF14 | c.3775G>A p.E1259K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.468); catalogued as COSV66261599; called by muse, mutect2, varscan2
- KIF3C | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV53099190; called by muse, mutect2, varscan2
- KLHL17 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs754744743, COSV58531705; called by muse, mutect2, varscan2
- KMT2E | c.3236C>G p.S1079* | Nonsense Mutation (SNP) | VAF 35/60 reads (58%) | catalogued as COSV57578777, COSV99996803, COSV99997164; called by muse, mutect2, varscan2
- KRT12 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760840954, COSV52430704; called by muse, mutect2, varscan2
- KRT78 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV58851652; called by muse, mutect2, varscan2
- KRTAP1-1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV60397848, COSV60398278; called by muse, mutect2, varscan2
- KXD1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); catalogued as COSV55889491; called by muse, mutect2, varscan2
- L3MBTL1 | c.832G>A p.E278K (on ENST00000418998 / NM_001377303.1; = p.E188K on NM_015478.7) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.874); catalogued as COSV64231726; called by muse, mutect2, varscan2
- LAMC3 | c.2942G>A p.G981D | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63090858; called by muse, mutect2, varscan2
- LANCL1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 74/148 reads (50%) | catalogued as COSV99286506; called by muse, mutect2, varscan2
- LIN54 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV61201013; called by muse, mutect2, varscan2
- LNX1 | c.2012T>C p.I671T (on ENST00000263925 / NM_001126328.3; = p.I575T on NM_032622.2) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs34296513; called by muse, mutect2, varscan2
- LRP1B | c.9691G>A p.D3231N | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs775616186, COSV67214828; called by muse, mutect2, varscan2
- LRRC36 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs781167042, COSV52079485; called by muse, mutect2, varscan2
- MAGEE2 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 42/42 reads (100%) | catalogued as rs1175875471, COSV100973238; called by muse, mutect2, varscan2
- MAP7D3 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 98/99 reads (99%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs779911007, COSV60170816; called by muse, mutect2, varscan2
- MARCHF8 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748603165, COSV100166019, COSV100166115, COSV60572107; called by muse, mutect2, varscan2
- MCF2 | c.2746-1G>C p.X916_splice | Splice Site (SNP) | VAF 19/20 reads (95%) | catalogued as COSV58484150; called by muse, mutect2, varscan2
- MECR | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV55285255; called by muse, mutect2, varscan2
- MKRN1 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99751940; called by muse, mutect2, varscan2
- MMD2 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV101287195, COSV68660442; called by muse, mutect2, varscan2
- MMP15 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.772); catalogued as COSV54679615; called by muse, mutect2, varscan2
- MMP15 | c.1299C>G p.F433L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV54679029; called by muse, mutect2, varscan2
- MOGAT3 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56174246; called by muse, mutect2, varscan2
- MROH7 | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV59871516; called by muse, mutect2, varscan2
- MUC4 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV62148325; called by muse, mutect2, varscan2
- MYO18B | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV59133405; called by muse, mutect2, varscan2
- MYO5C | c.4840G>A p.E1614K | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55905739; called by muse, mutect2, varscan2
- NADK2 | c.584C>T p.P195L (on ENST00000381937 / NM_001085411.3; = p.P32L on NM_153013.4) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV56936364; called by muse, mutect2, varscan2
- NANOG | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99981775; called by muse, mutect2, varscan2
- NBAS | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV55720442; called by muse, mutect2
- NDST4 | c.1139T>C p.M380T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV52118425; called by muse, mutect2, varscan2
- NID2 | c.1534T>C p.C512R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761414747, COSV53495960; called by muse, mutect2, varscan2
- NLRP11 | c.2758G>C p.E920Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV64086920; called by muse, mutect2, varscan2
- NMBR | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV57801125; called by muse, mutect2, varscan2
- NOB1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 69/126 reads (55%) | catalogued as COSV99264119; called by muse, mutect2, varscan2
- NOL9 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV66625931; called by muse, mutect2, varscan2
- NPEPPS | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59102347; called by muse, mutect2, varscan2
- NPEPPS | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV59102356; called by muse, varscan2
- NPHS1 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV62287658; called by muse, mutect2, varscan2
- OMG | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.203); catalogued as COSV55987988, COSV55988230; called by muse, mutect2, varscan2
- OR4A16 | c.536T>C p.M179T | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV59042976; called by muse, mutect2, varscan2
- OR5AK2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58804425; called by muse, mutect2, varscan2
- OR7E24 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV71702205; called by muse, mutect2, varscan2
- PA2G4 | c.1010C>G p.P337R | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV57568407; called by muse, mutect2, varscan2
- PACS1 | c.2244C>A p.F748L | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57697520; called by muse, mutect2, varscan2
- PAX1 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101270184, COSV68271029, COSV68271784; called by muse, mutect2, varscan2
- PCDH15 | c.4006G>C p.D1336H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57304285, COSV57327137; called by muse, mutect2, varscan2
- PCDHGA1 | c.1245C>G p.I415M | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as COSV65296300; called by muse, mutect2, varscan2
- PCDHGA1 | c.1960C>T p.L654F | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs149280390; called by muse, mutect2, varscan2
- PDE11A | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53693488; called by muse, mutect2, varscan2
- PER3 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62705638; called by muse, mutect2, varscan2
- PER3 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV62705644, COSV62706505; called by muse, varscan2
- PER3 | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62705648; called by muse, varscan2
- PER3 | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV62705663; called by muse, varscan2
- PGM2L1 | c.1348G>T p.G450W | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53346618; called by muse, mutect2, varscan2
- PHF11 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV62896459; called by muse, mutect2, varscan2
- PHRF1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52755246; called by muse, mutect2, varscan2
- PITHD1 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV55754889; called by muse, mutect2, varscan2
- PIWIL2 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63251286, COSV63254526; called by muse, mutect2, varscan2
- PJA2 | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV63272677; called by muse, mutect2, varscan2
- PKHD1L1 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65742400; called by muse, mutect2, varscan2
- PKHD1L1 | c.5978T>C p.V1993A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1285929897, COSV65741629; called by muse, mutect2, varscan2
- PLOD3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99778348; called by muse, mutect2, varscan2
- PML | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760154145, COSV51446075; called by muse, mutect2, varscan2
- PNPLA6 | c.186G>A p.M62I (on ENST00000414982 / NM_001166111.2; = p.M14I on NM_006702.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99654655; called by muse, varscan2
- POLM | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs747067143, COSV54242496; called by muse, varscan2
- PPFIA3 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV61949793, COSV61951470; called by muse, mutect2, varscan2
- PPIP5K2 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV58605347; called by muse, mutect2, varscan2
- PPIP5K2 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV58605355, COSV58608335; called by muse, mutect2, varscan2
- PPP1R36 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 160/335 reads (48%) | catalogued as COSV100073087, COSV53903512; called by muse, mutect2, varscan2
- PRCC | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV54858009; called by muse, mutect2
- PRKAA2 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as COSV64803540; called by muse, mutect2, varscan2
- PSMA4 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 40/118 reads (34%) | catalogued as COSV99245656; called by muse, mutect2, varscan2
- PTPRD | c.3477G>C p.E1159D | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61943683, COSV61945247; called by muse, mutect2, varscan2
- PUS10 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV57452155; called by muse, mutect2, varscan2
- PXDN | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 99/183 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.685); catalogued as COSV53233024; called by muse, mutect2, varscan2
- RAB33A | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 32/33 reads (97%) | catalogued as COSV57061357, COSV99924726; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2528T>G p.I843S | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV51481867; called by muse, mutect2, varscan2
- RAB6A | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60178283; called by muse, mutect2, varscan2
- RBM12 | c.1951G>C p.G651R | Missense Mutation (SNP) | VAF 83/118 reads (70%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100466836, COSV58291151; called by muse, varscan2
- RBM12 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 130/195 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV58291157; called by muse, varscan2
- RBM47 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55934552, COSV99920586; called by muse, mutect2, varscan2
- RC3H1 | c.2570G>C p.R857T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51200270; called by muse, mutect2, varscan2
- REXO5 | c.1340C>G p.S447C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54471907, COSV54472905; called by muse, mutect2, varscan2
- RFWD3 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs369856889, COSV100736209; called by muse, mutect2, varscan2
- RFX6 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV100264405; called by muse, mutect2, varscan2
- RFXAP | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV55225527, COSV99715247; called by muse, mutect2, varscan2
- RHOBTB1 | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs770398947, COSV61958464; called by muse, mutect2, varscan2
- RPS6KA5 | c.2391C>G p.F797L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.878); catalogued as COSV56221808; called by muse, mutect2, varscan2
- RYR3 | c.10204G>C p.D3402H (on ENST00000389232; = p.D3403H on NM_001036.6) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66787350, COSV66799653; called by muse, mutect2, varscan2
- RYR3 | c.10754A>G p.K3585R (on ENST00000389232; = p.K3586R on NM_001036.6) | Missense Mutation (SNP) | VAF 325/511 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV66787356; called by muse, mutect2, varscan2
- S100A7A | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV61330473, COSV61331242; called by muse, mutect2, varscan2
- SF3B4 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV54965319, COSV54966050; called by muse, mutect2, varscan2
- SFR1 | c.661C>T p.Q221* (on ENST00000369727 / NM_001002759.1; = p.Q208* on NM_145247.4) | Nonsense Mutation (SNP) | VAF 36/78 reads (46%) | catalogued as COSV100312459; called by muse, mutect2, varscan2
- SIGLEC1 | c.2875C>G p.H959D | Missense Mutation (SNP) | VAF 73/115 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52458028, COSV52463390; called by muse, mutect2, varscan2
- SLC12A7 | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs751647758, COSV53756540, COSV99370725; called by muse, mutect2, varscan2
- SLC22A11 | c.1212C>G p.I404M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV57253048; called by muse, mutect2, varscan2
- SLC6A8 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53472122; called by muse, mutect2, varscan2
- SMC3 | c.497G>C p.R166T | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100699746, COSV62420074; called by muse, mutect2, varscan2
- SMCHD1 | c.3544C>T p.Q1182* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99862803; called by muse, mutect2, varscan2
- SORBS1 | c.397G>C p.G133R (on ENST00000361941 / NM_001034954.2; = p.G92R on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53357119; called by muse, mutect2, varscan2
- SORCS3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV63794329; called by muse, mutect2, varscan2
- SOS1 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 79/143 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as COSV101217121, COSV67675083; called by muse, mutect2, varscan2
- SP8 | c.-132G>T | Splice Region (SNP) | VAF 112/226 reads (50%) | catalogued as COSV63866216; called by muse, mutect2, varscan2
- SRRM2 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57072744; called by muse, mutect2, varscan2
- SUPT16H | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53524385; called by muse, mutect2, varscan2
- SURF4 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64332307; called by muse, mutect2, varscan2
- SYCP1 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1023922541, COSV65697105; called by muse, mutect2, varscan2
- SYCP2L | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV51652867, COSV51654109; called by muse, mutect2, varscan2
- TBC1D16 | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60477408; called by muse, mutect2, varscan2
- TENM3 | c.6127C>G p.L2043V | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV69301690, COSV69306973; called by muse, mutect2, varscan2
- TEX14 | c.3824C>G p.S1275C (on ENST00000240361 / NM_001201457.2; = p.S1229C on NM_031272.5) | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV53615743, COSV53616289; called by muse, mutect2, varscan2
- TGS1 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV52699821; called by muse, mutect2, varscan2
- THRAP3 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 40/84 reads (48%) | catalogued as COSV100663675, COSV63567626; called by muse, mutect2, varscan2
- THSD7B | c.4183G>C p.E1395Q (on ENST00000272643; = p.E1393Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV55682396; called by muse, mutect2, varscan2
- TLE3 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58169033; called by muse, mutect2, varscan2
- TMEM102 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 55/58 reads (95%) | catalogued as COSV99548561; called by muse, mutect2, varscan2
- TMEM131L | c.2703G>C p.M901I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.297); catalogued as COSV53644069; called by muse, mutect2, varscan2
- TNFAIP1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 138/201 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56876520; called by muse, mutect2, varscan2
- TNXB | c.10116G>C p.K3372N (on ENST00000647633; = p.K3125N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64478409; called by muse, mutect2, varscan2
- TNXB | c.2423G>C p.R808T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as COSV100926590, COSV64478413; called by muse, mutect2, varscan2
- TRIM22 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603016, COSV66090796; called by muse, mutect2, varscan2
- TTN | c.42365T>A p.L14122* (on ENST00000591111; = p.L6698* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 38/77 reads (49%) | catalogued as COSV100634232, COSV104415648; called by muse, mutect2, varscan2
- UBR3 | c.3923C>T p.S1308L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55848801; called by muse, mutect2, varscan2
- UBXN7 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56355476, COSV56357860; called by muse, mutect2, varscan2
- USP24 | c.2722G>A p.V908I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV99601200; called by muse, mutect2
- USP33 | c.1936C>A p.L646I | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV62469276; called by muse, mutect2, varscan2
- USP40 | c.2497C>T p.L833F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52480315; called by muse, mutect2, varscan2
- VPS13C | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 17/26 reads (65%) | catalogued as COSV99830570; called by muse, mutect2, varscan2
- VPS13D | c.11281G>C p.E3761Q | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV50636618; called by muse, mutect2, varscan2
- VPS28 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as rs151274166, COSV52871770; called by muse, mutect2, varscan2
- VWA5A | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs761407480, COSV63707566; called by muse, mutect2, varscan2
- XKR3 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV58885960; called by muse, mutect2, varscan2
- YAF2 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100586498; called by muse, mutect2, varscan2
- ZCCHC14 | c.1097C>T p.S366L (on ENST00000268616; = p.S503L on NM_015144.3) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs748819715, COSV51883599; called by muse, varscan2
- ZFAND2B | c.589-1G>C p.X197_splice | Splice Site (SNP) | VAF 63/146 reads (43%) | catalogued as rs770671318, COSV54695674; called by muse, mutect2, varscan2
- ZIC1 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV51553094; called by muse, varscan2
- ZNF148 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as COSV62304403, COSV62307667; called by muse, mutect2, varscan2
- ZNF319 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV54622025; called by muse, mutect2, varscan2
- ZNF346 | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56156322; called by muse, mutect2, varscan2
- ZNF407 | c.6448G>A p.E2150K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs951378695, COSV55251637; called by muse, mutect2, varscan2
- ZNF415 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV54700876; called by muse, mutect2, varscan2
- ZNF438 | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59194732; called by muse, mutect2, varscan2
- ZNF486 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV58718891; called by muse, mutect2, varscan2
- ZNF540 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57109122, COSV57111254; called by muse, mutect2, varscan2
- ZNF665 | c.1637C>T p.S546L (on ENST00000600412; = p.S611L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs763626087, COSV67214587; called by muse, mutect2, varscan2
- ZNF665 | c.814C>G p.Q272E (on ENST00000600412; = p.Q337E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV67214856; called by muse, mutect2, varscan2
- ZNF665 | c.706C>G p.Q236E (on ENST00000600412; = p.Q301E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV67214575, COSV67214867; called by muse, mutect2, varscan2
- ZNF665 | c.534C>A p.F178L (on ENST00000600412; = p.F243L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67214876; called by muse, mutect2, varscan2
- ZNF665 | c.245C>A p.S82* (on ENST00000600412; = p.S147* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/158 reads (38%) | catalogued as COSV101128924; called by muse, mutect2, varscan2
- ZSWIM5 | c.1802G>A p.W601* | Nonsense Mutation (SNP) | VAF 51/101 reads (50%) | catalogued as COSV100655893; called by muse, mutect2, varscan2
- ACAA1 | c.292dup p.A98Gfs*12 | Frame Shift Ins (INS) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- C1QTNF2 | c.524del p.G175Afs*27 (on ENST00000393975; = p.G130Afs*27 on NM_031908.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 81/217 reads (37%) | called by mutect2, pindel, varscan2
- CMYA5 | c.10357C>T p.Q3453* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2
- OR4N2 | c.238dup p.R80Pfs*42 | Frame Shift Ins (INS) | VAF 91/373 reads (24%) | called by mutect2, pindel, varscan2
- PHTF2 | c.717_741del p.S240Efs*68 (on ENST00000248550 / NM_001366089.1; = p.S202Efs*68 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | called by mutect2, pindel
- THAP3 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TRAV18 | c.322T>C p.C108R | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH1L2 | c.1704C>T p.I568= | Silent (SNP) | VAF 86/148 reads (58%) | catalogued as COSV51555590; called by muse, mutect2, varscan2
- AREL1 | c.2469C>G p.L823= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as COSV62666347; called by muse, mutect2, varscan2
- ARHGEF19 | c.474C>T p.V158= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV54616476; called by muse, mutect2
- ASIC2 | c.1050G>A p.L350= | Silent (SNP) | VAF 105/188 reads (56%) | catalogued as COSV56759991; called by muse, mutect2, varscan2
- CACNA1S | c.1374C>T p.L458= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV62939153; called by muse, mutect2
- CCDC180 | c.1491G>A p.L497= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as COSV100827396; called by muse, mutect2, varscan2
- CCDC9B | c.90C>T p.L30= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1379549552, COSV66875333; called by muse, mutect2, varscan2
- CDT1 | c.495G>A p.E165= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV56347787; called by muse, mutect2, varscan2
- CEP290 | c.4404A>G p.L1468= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as rs779186037, COSV58351423; called by muse, mutect2, varscan2
- CSNK1A1L | c.1011C>T p.N337= | Silent (SNP) | VAF 63/118 reads (53%) | catalogued as COSV65789638; called by muse, mutect2, varscan2
- CYLD | c.2058G>A p.L686= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100282802; called by muse, mutect2, varscan2
- DNAH8 | c.1146T>C p.Y382= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs769651416, COSV59443040; called by muse, mutect2, varscan2
- DSCAM | c.1476C>T p.V492= | Silent (SNP) | VAF 43/45 reads (96%) | catalogued as rs1345012604, COSV68024105; called by muse, mutect2, varscan2
- EIF3K | c.639C>T p.I213= | Silent (SNP) | VAF 34/185 reads (18%) | catalogued as COSV50264023; called by muse, mutect2, varscan2
- EMP3 | c.243C>T p.F81= | Silent (SNP) | VAF 74/125 reads (59%) | catalogued as COSV53156378; called by muse, mutect2, varscan2
- EMSY | c.3768C>T p.I1256= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV58259904; called by muse, mutect2, varscan2
- EPPK1 | c.6648C>T p.V2216= | Silent (SNP) | VAF 86/159 reads (54%) | catalogued as COSV73261155; called by muse, mutect2, varscan2
- EXOC8 | c.2010G>A p.K670= | Silent (SNP) | VAF 148/192 reads (77%) | catalogued as COSV50478097, COSV50478973; called by muse, mutect2, varscan2
- FAM71A | c.372G>A p.L124= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs1230006037, COSV54235555; called by muse, mutect2, varscan2
- FASTK | c.669G>C p.L223= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV52539956; called by muse, mutect2, varscan2
- FBXL6 | c.96G>A p.P32= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1429375753, COSV100095605, COSV57351743; called by muse, mutect2, varscan2
- FBXO44 | c.450G>A p.L150= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV52354141; called by muse, mutect2, varscan2
- FCRL1 | c.1206T>C p.H402= | Silent (SNP) | VAF 116/148 reads (78%) | catalogued as COSV63825034; called by muse, mutect2, varscan2
- FECH | c.765G>A p.E255= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV50490809; called by muse, mutect2
- FGFR2 | c.489A>G p.E163= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV60646389; called by muse, mutect2, varscan2
- FGFR3 | c.240G>A p.G80= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV53400499; called by muse, mutect2, varscan2
- FLAD1 | c.1470G>A p.R490= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV52696939; called by muse, mutect2, varscan2
- FSD1 | c.36C>T p.I12= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV55695975; called by muse, mutect2, varscan2
- GPATCH8 | c.4341C>T p.I1447= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV59194699; called by muse, mutect2, varscan2
- GPR176 | c.93C>T p.L31= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as rs1164859962, COSV54444880; called by muse, mutect2, varscan2
- GTF3C1 | c.2988G>A p.L996= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV62240992; called by muse, mutect2, varscan2
- H2AC17 | c.183C>T p.A61= | Silent (SNP) | VAF 93/209 reads (44%) | catalogued as rs750518607, COSV58152560; called by muse, mutect2, varscan2
- H6PD | c.1545C>T p.F515= | Silent (SNP) | VAF 62/239 reads (26%) | catalogued as rs781226821, COSV66230955; called by muse, mutect2, varscan2
- H6PD | c.2016C>A p.I672= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV66230160; called by muse, mutect2, varscan2
- HTR1E | c.333C>G p.L111= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV59507981; called by muse, mutect2, varscan2
- IFIH1 | c.544C>T p.L182= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV55126488; called by muse, mutect2, varscan2
- ITPR2 | c.6630G>A p.Q2210= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs1304375069, COSV67268922; called by muse, mutect2, varscan2
- JARID2 | c.1356G>A p.K452= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV59188911; called by muse, mutect2, varscan2
- KDM1B | c.2292C>T p.I764= (on ENST00000449850; = p.I531= on NM_153042.4) | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV52810402; called by muse, mutect2, varscan2
- KIF23 | c.2013G>A p.R671= | Silent (SNP) | VAF 60/111 reads (54%) | catalogued as COSV52979442; called by muse, mutect2, varscan2
- LAMC3 | c.921C>T p.F307= | Silent (SNP) | VAF 62/64 reads (97%) | catalogued as COSV63090849; called by muse, mutect2, varscan2
- LCMT2 | c.582C>G p.L194= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV59790323; called by muse, mutect2, varscan2
- LDHAL6B | c.360C>T p.F120= | Silent (SNP) | VAF 61/200 reads (31%) | catalogued as COSV55686546; called by muse, mutect2, varscan2
- LINS1 | c.1326C>T p.F442= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV59078826; called by muse, mutect2, varscan2
- LRATD2 | c.777G>A p.Q259= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV59230081; called by muse, mutect2, varscan2
- MED23 | c.3087G>A p.A1029= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs535835226, COSV63432340; called by muse, mutect2, varscan2
- MRC1 | c.2577A>G p.A859= | Silent (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- MYH1 | c.1056C>T p.I352= | Silent (SNP) | VAF 50/52 reads (96%) | catalogued as COSV56847932; called by muse, mutect2, varscan2
- NBAS | c.1014C>T p.F338= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as COSV55720453; called by muse, mutect2
- NLRP13 | c.2400G>A p.L800= | Silent (SNP) | VAF 72/187 reads (39%) | catalogued as rs867839181, COSV61621525; called by muse, mutect2, varscan2
- NRXN1 | c.1395C>A p.I465= | Silent (SNP) | VAF 69/150 reads (46%) | catalogued as COSV58450031; called by muse, mutect2, varscan2
- OR10P1 | c.225T>C p.T75= | Silent (SNP) | VAF 69/122 reads (57%) | catalogued as rs749155907, COSV59007222; called by muse, mutect2, varscan2
- OR9Q1 | c.342C>G p.L114= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as COSV59039895; called by muse, mutect2, varscan2
- OTUD6A | c.846C>T p.G282= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as rs1440683442, COSV57973246; called by muse, mutect2, varscan2
- PCDHA10 | c.804G>A p.S268= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs1023415818, COSV56498268; called by muse, mutect2, varscan2
- PCDHB12 | c.663C>T p.P221= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV53396285, COSV99507017; called by muse, mutect2, varscan2
- PCDHB14 | c.1890G>A p.L630= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV99506364; called by muse, mutect2, varscan2
- PCDHGA1 | c.456C>G p.V152= | Silent (SNP) | VAF 77/166 reads (46%) | catalogued as COSV65296284; called by muse, mutect2, varscan2
- PCDHGA1 | c.630C>T p.L210= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV65296291; called by muse, mutect2, varscan2
- PCDHGA4 | c.1653C>T p.F551= | Silent (SNP) | VAF 103/218 reads (47%) | catalogued as COSV53941730; called by muse, mutect2, varscan2
- PCLAF | c.237G>A p.E79= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV55540226; called by muse, mutect2, varscan2
- PER3 | c.2259G>A p.S753= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs768315671, COSV62705656; called by muse, mutect2, varscan2
- PHF2 | c.264C>G p.L88= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as COSV63680700; called by muse, mutect2, varscan2
- PLA2G4A | c.1620C>G p.V540= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV66553692; called by muse, mutect2, varscan2
- PLEC | c.7131G>A p.L2377= (on ENST00000322810 / NM_201380.4; = p.L2267= on NM_000445.5) | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100517104, COSV59632689; called by muse, mutect2, varscan2
- PLOD3 | c.612G>T p.L204= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as COSV56181439, COSV56182750, COSV99778051; called by muse, mutect2, varscan2
- PLPPR4 | c.2133C>T p.S711= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV64565324, COSV64565634; called by muse, mutect2, varscan2
- RAPGEF4 | c.486T>C p.Y162= | Silent (SNP) | VAF 73/160 reads (46%) | catalogued as rs771351257, COSV51387440; called by muse, mutect2, varscan2
- RBM15 | c.75G>C p.T25= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs754063032, COSV63923448; called by muse, mutect2, varscan2
- RBM47 | c.606G>A p.E202= | Silent (SNP) | VAF 75/138 reads (54%) | catalogued as COSV55930959, COSV55934575, COSV55944676; called by muse, mutect2, varscan2
- SFXN2 | c.738C>T p.I246= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV64012196; called by muse, mutect2, varscan2
- SIGLEC12 | c.1620G>A p.P540= (on ENST00000291707 / NM_053003.4; = p.P422= on NM_033329.2) | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs760555987, COSV52459837; called by muse, mutect2, varscan2
- SLC22A11 | c.1095C>T p.F365= | Silent (SNP) | VAF 89/210 reads (42%) | catalogued as COSV57253040; called by muse, mutect2, varscan2
- SLC24A3 | c.873C>T p.C291= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs772430227, COSV60118850; called by muse, mutect2, varscan2
- SLC25A17 | c.225C>G p.L75= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV54351186; called by muse, mutect2, varscan2
- SLC9A1 | c.2211G>A p.L737= | Silent (SNP) | VAF 155/363 reads (43%) | catalogued as COSV56053232; called by muse, mutect2, varscan2
- SPEN | c.9294G>A p.V3098= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV65361387; called by muse, mutect2, varscan2
- SPTA1 | c.1068T>A p.R356= | Silent (SNP) | VAF 148/196 reads (76%) | catalogued as COSV63752544; called by muse, mutect2, varscan2
- SRRM4 | c.60C>T p.F20= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57415250; called by muse, mutect2, varscan2
- TANC2 | c.270C>A p.L90= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV67333993; called by muse, mutect2, varscan2
- TENM3 | c.534C>G p.G178= | Silent (SNP) | VAF 98/228 reads (43%) | catalogued as COSV69306964; called by muse, mutect2, varscan2
- TLE1 | c.1989G>A p.L663= | Silent (SNP) | VAF 35/37 reads (95%) | catalogued as COSV64720792; called by muse, mutect2, varscan2
- TPP2 | c.1332G>A p.L444= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs1001390340, COSV65752448; called by muse, mutect2, varscan2
- TRAJ52 | c.33G>C p.L11= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- TRANK1 | c.7848C>A p.V2616= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100085154; called by muse, mutect2
- TUBA3C | c.675C>T p.T225= | Silent (SNP) | VAF 106/254 reads (42%) | catalogued as COSV67139210; called by muse, mutect2, varscan2
- UBIAD1 | c.564C>T p.L188= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs774211411, COSV65147731; called by muse, mutect2, varscan2
- VWF | c.7218C>T p.P2406= | Silent (SNP) | VAF 64/117 reads (55%) | catalogued as COSV54619162; called by muse, mutect2, varscan2
- WDR3 | c.1269C>T p.F423= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV62522848, COSV62523229; called by muse, mutect2, varscan2
- ZBTB46 | c.93C>T p.C31= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs374215565; called by muse, mutect2
- ZIC1 | c.882C>T p.R294= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV51553079; called by muse, varscan2
- ZMAT4 | c.519G>A p.A173= | Silent (SNP) | VAF 94/232 reads (41%) | catalogued as rs747874868, COSV52698156; called by muse, mutect2, varscan2
- ZNF665 | c.1791C>G p.V597= (on ENST00000600412; = p.V662= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV101128502, COSV67214826; called by muse, mutect2, varscan2
- ZNF804A | c.3606C>T p.V1202= | Silent (SNP) | VAF 128/259 reads (49%) | catalogued as COSV56447061; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4624G>C | Intron (SNP) | VAF 29/56 reads (52%) | catalogued as COSV99385731; called by muse, mutect2, varscan2
- BCL2L2 | c.-2G>A | 5'UTR (SNP) | VAF 28/128 reads (22%) | catalogued as rs1311255385, COSV99161717; called by muse, mutect2, varscan2
- CCT6A | c.1213+154C>G | Intron (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99303153, COSV99303826; called by mutect2, varscan2
- DCHS2 | n.1661C>A | RNA (SNP) | VAF 51/91 reads (56%) | catalogued as COSV59725587; called by muse, mutect2, varscan2
- FBXW7 | c.502-2400G>A | Intron (SNP) | VAF 30/74 reads (41%) | catalogued as COSV55913673; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516082 C>T | 5'Flank (SNP) | VAF 24/87 reads (28%) | catalogued as COSV53063502; called by muse, mutect2, varscan2
- PDE4B | c.635-95C>T | Intron (SNP) | VAF 51/95 reads (54%) | catalogued as COSV58475672; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7687C>T | Intron (SNP) | VAF 20/128 reads (16%) | catalogued as COSV100521994, COSV57689637; called by muse, mutect2, varscan2
- PTHLH | c.-22-177G>A | Intron (SNP) | VAF 20/51 reads (39%) | catalogued as COSV52367088; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TMEM105 | n.789G>A | RNA (SNP) | VAF 141/213 reads (66%) | catalogued as COSV59655140; called by muse, mutect2, varscan2
